Gene-level copy-number profile of tumor specimen TCGA-64-1678-01A from TCGA case TCGA-64-1678, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 71.0 years (25,931 days).
Specimen TCGA-64-1678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e0e5dde3-723b-4b01-afd6-db7bffd97dd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-64-1678-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb6d06c2-a1df-45fe-a870-e83dd0488b68

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 677; copy number 2: 15,915; copy number 3: 27,300; copy number 4: 11,766; copy number 5: 2,510; copy number 6: 1,038; copy number 7: 44; copy number 8: 72; copy number 9: 119; copy number 10: 205; copy number 11: 25; copy number 13: 49; copy number 14: 57; copy number 19: 9; copy number 23: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-64-1678-01): tumor purity 0.57, ploidy 3.11, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 601 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:53,951,504–54,075,583, 3 genes, copy number 8: MIR581, RN7SL801P, AC016601.1.
- chr5:54,643,557–54,878,588, 5 genes, copy number 8: AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3.
- chr11:68,460,731–68,615,334, 1 gene, copy number 23 (within-gene range 3–23): PPP6R3.
- chr11:68,612,899–69,704,022, 31 genes, copy number 19–23: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19.
- chr13:26,094,724–31,846,539, 114 genes, copy number 7–9 (broad region; genes not listed).
- chr14:28,592,223–40,390,547, 203 genes, copy number 10 (broad region; genes not listed).
- chr15:69,022,230–74,756,607, 146 genes, copy number 8–14 (broad region; genes not listed).
- chr21:21,566,763–21,975,681, 5 genes, copy number 9: AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1.
- chr22:36,226,209–38,273,010, 93 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 473. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
